Gene-level copy-number profile of tumor specimen C3N-02729-01 (profiled together with C3N-02729-02) from CPTAC case C3N-02729, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 45.7 years (16,705 days).
Specimen C3N-02729-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42aef953-29c7-47b3-a9aa-a53a90b57136.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02729-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/47376e9e-7a01-409f-b3b3-950b9fa2a685

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 24,914; copy number 2: 30,434; copy number 3: 3,251; copy number 4: 212; copy number 5: 15; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:20,350,210–20,700,152, 3 genes: AC023403.1, AC022559.1, AC018541.1.
- chr9:20,331,446–22,455,740, 66 genes (broad region; genes not listed).
- chr19:40,843,541–40,850,447, 1 gene (within-gene range 0–1): CYP2A6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:6,532,467–6,645,729, 1 gene, copy number 5 (within-gene range 3–5): GLDC.
- chr9:6,568,844–7,175,648, 14 genes, copy number 5: AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1.
- chr21:13,038,160–13,120,807, 4 genes, copy number 6: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 22,058. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
